Somatic mutation profile of tumor specimen TCGA-49-4487-01A (aliquot TCGA-49-4487-01A-21D-1855-08) from TCGA case TCGA-49-4487, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.8 years (26,583 days).
Specimen TCGA-49-4487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d81816b6-49c1-4f0e-9798-5e50a0d44582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-4487-11A (Solid Tissue Normal), aliquot TCGA-49-4487-11A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6d87a44-2ad8-42e6-aeae-f14e1c584b3a

The open-access MAF lists 364 somatic variants for this specimen: 278 protein-altering or splice-affecting, 77 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 77, Nonsense Mutation 20, Frame Shift Del 9, Splice Site 6, RNA 4, Intron 3, Splice Region 2, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- AACS | c.1432G>T p.V478F | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55540225; called by muse, mutect2, varscan2
- ADAM23 | c.1527C>G p.Y509* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV52229394, COSV52230827; called by muse, mutect2, varscan2
- ADGRL3 | c.1903A>G p.T635A (on ENST00000506720 / NM_001322402.2; = p.T567A on NM_015236.6) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV63368563; called by muse, mutect2
- AHR | c.1151G>A p.R384K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV54126143; called by muse, mutect2
- AKR7A2 | c.591+1G>T p.X197_splice | Splice Site (SNP) | VAF 10/74 reads (14%) | catalogued as COSV52516851; called by muse, mutect2, varscan2
- AMY2B | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 27/673 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV63716994; called by muse, mutect2
- ANKRD30A | c.2143G>T p.G715* (on ENST00000611781; = p.G659* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV64605915; called by mutect2, varscan2
- ANTXR1 | c.225-2A>T p.X75_splice | Splice Site (SNP) | VAF 6/80 reads (8%) | catalogued as COSV58021474; called by muse, mutect2
- APOC2 | c.305A>T p.*102Lext*23 | Nonstop Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99377010; called by muse, mutect2, varscan2
- ARAP2 | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1351881777, COSV100394976; called by muse, mutect2, varscan2
- ARMC3 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV53067416; called by muse, mutect2, varscan2
- ARSK | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs779685757, COSV66170466; called by muse, mutect2, varscan2
- ASIC2 | c.591C>A p.N197K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56769925; called by muse, mutect2, varscan2
- ATP7B | c.1789G>T p.V597F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM133426, COSV54439147, COSV54443836; called by muse, mutect2, varscan2
- AXDND1 | c.2694A>T p.E898D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.073); catalogued as COSV62648079; called by muse, mutect2, varscan2
- BAHD1 | c.2152A>T p.R718W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69084712; called by muse, mutect2, varscan2
- BCL2L11 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as rs1431222585, COSV58029191, COSV58032775; called by muse, mutect2, varscan2
- BEND2 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV66217201; called by muse, mutect2, varscan2
- BPIFB2 | c.1280C>G p.A427G | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV50070404; called by muse, mutect2, varscan2
- BPTF | c.2072G>A p.C691Y | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV58834776; called by muse, mutect2, varscan2
- BRINP1 | c.120G>T p.W40C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV56301518, COSV56312569; called by muse, mutect2, varscan2
- BTBD11 | c.2939T>A p.L980H (on ENST00000280758 / NM_001018072.2; = p.L517H on NM_001017523.2) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55036863; called by muse, mutect2
- BYSL | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100026933, COSV57829618; called by muse, mutect2, varscan2
- C12orf40 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs1179490588, COSV61137532; called by muse, mutect2
- CARD14 | c.1881C>G p.F627L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV60126628; called by muse, mutect2
- CCDC102B | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 16/134 reads (12%) | catalogued as COSV60153592; called by muse, mutect2, varscan2
- CCDC141 | c.2863C>A p.Q955K | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99837136; called by muse, mutect2
- CCDC144A | c.1362G>C p.M454I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV60701735; called by muse, varscan2
- CCDC74A | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54609074; called by muse, mutect2
- CCR8 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58337947; called by muse, mutect2, varscan2
- CD163L1 | c.2797G>A p.D933N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.605); catalogued as rs756923205, COSV58024200; called by muse, mutect2, varscan2
- CDC14A | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV60563364; called by muse, mutect2
- CDC42BPA | c.2863G>C p.A955P | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.53); catalogued as COSV62020234; called by muse, mutect2
- CDHR2 | c.3896C>A p.S1299Y | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV56144892; called by muse, mutect2, varscan2
- CEL | c.850A>T p.T284S (on ENST00000673714; = p.T281S on NM_001807.6) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.196); catalogued as COSV60829535; called by muse, mutect2, varscan2
- CEP135 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99954696, COSV99954893; called by muse, mutect2
- CEP164 | c.3610-1G>T p.X1204_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV54046077; called by muse, varscan2
- CEP350 | c.2966G>T p.S989I | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62609406; called by muse, mutect2
- CHD6 | c.262G>A p.G88R | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.011); catalogued as COSV58562220; called by muse, mutect2
- CLDN8 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.102); catalogued as COSV54527466; called by muse, mutect2
- COL16A1 | c.1620G>T p.R540S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54713504; called by muse, mutect2, varscan2
- COL5A1 | c.4807G>T p.D1603Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100880211; called by mutect2, varscan2
- COL6A3 | c.8707C>A p.P2903T | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV55108553; called by muse, mutect2
- COPS3 | c.1081C>T p.H361Y | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV99253777; called by muse, mutect2
- CPA1 | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 29/493 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.156); catalogued as COSV50575045, COSV99163402; called by muse, mutect2
- CPA3 | c.443C>A p.T148N | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56047260; called by muse, mutect2, varscan2
- CPEB1 | c.1395G>C p.E465D (on ENST00000617958; = p.E400D on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV55621358; called by muse, mutect2, varscan2
- CRNN | c.1223C>A p.A408E | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV55123773; called by muse, mutect2, varscan2
- CTC1 | c.1309C>T p.Q437* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | catalogued as COSV59855409; called by muse, mutect2, varscan2
- CTSF | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59750410; called by muse, mutect2, varscan2
- CTTNBP2 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866299576, COSV50394984, COSV99354428; called by muse, mutect2
- CTTNBP2 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV99354433; called by muse, mutect2
- DCDC1 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV60857878; called by muse, mutect2, varscan2
- DDHD2 | c.1813C>G p.P605A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.023); catalogued as COSV68158762; called by muse, mutect2
- DDX43 | c.1475T>C p.V492A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV64813759; called by muse, mutect2, varscan2
- DEF6 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.039); catalogued as COSV57355360; called by muse, mutect2, varscan2
- DISP1 | c.3937G>T p.A1313S | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as COSV99451601; called by muse, mutect2, varscan2
- DNAH2 | c.2489G>T p.R830L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV101208998, COSV66726799; called by muse, mutect2, varscan2
- DNAJC13 | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs1242920871, COSV53455381, COSV53457808; called by muse, mutect2
- DST | c.10118G>T p.G3373V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.572); catalogued as COSV99758289; called by muse, mutect2, varscan2
- DUSP10 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.003); catalogued as COSV60459653; called by muse, mutect2, varscan2
- EFCAB5 | c.3918A>G p.I1306M | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1404795825, COSV57937017; called by muse, mutect2, varscan2
- EIF4G1 | c.3054C>G p.I1018M (on ENST00000346169 / NM_198241.3; = p.I823M on NM_004953.5) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV59993732; called by muse, mutect2, varscan2
- ELAC2 | c.1286C>G p.P429R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1285444804, COSV62031632; called by muse, mutect2
- ENKUR | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58634796; called by muse, mutect2, varscan2
- EPB41L3 | c.3127G>T p.G1043W | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59467295; called by muse, mutect2, varscan2
- EPB41L3 | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV59467321; called by muse, mutect2
- EPHX4 | c.511G>T p.G171W | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100952732; called by muse, mutect2, varscan2
- EPHX4 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64889902; called by muse, mutect2, varscan2
- ESF1 | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV52524201; called by muse, mutect2, varscan2
- EXOC4 | c.2274G>C p.Q758H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV54121570; called by muse, mutect2
- EXTL1 | c.524T>A p.L175Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV65337756, COSV65337916; called by muse, mutect2
- FAT1 | c.11611G>A p.A3871T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as COSV71675925; called by muse, mutect2, varscan2
- FAT4 | c.13093G>C p.D4365H | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV58707696; called by muse, mutect2
- FBN1 | c.5084G>T p.C1695F | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as CM138475, COSV57312693, COSV57329613; called by muse, mutect2, varscan2
- FBXL13 | c.574A>T p.N192Y | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV57544100; called by muse, mutect2, varscan2
- FCRL1 | c.887-1G>T p.X296_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as COSV63827345; called by muse, mutect2, varscan2
- FLG | c.11347C>T p.H3783Y | Missense Mutation (SNP) | VAF 282/883 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV64248524; called by muse, mutect2, varscan2
- FLG | c.887G>T p.R296I | Missense Mutation (SNP) | VAF 95/699 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV64248531; called by muse, mutect2, varscan2
- FLG2 | c.4395C>A p.H1465Q | Missense Mutation (SNP) | VAF 222/755 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV66172982; called by muse, varscan2
- FOXP2 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV63483930, COSV63486114; called by muse, mutect2
- FPR2 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV60674358; called by muse, mutect2, varscan2
- FTCD | c.474G>T p.W158C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52429677; called by muse, mutect2, varscan2
- FYCO1 | c.1744C>A p.Q582K | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.85); PolyPhen benign (0.013); catalogued as COSV56119385; called by muse, mutect2
- FZD10 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57475770; called by muse, mutect2
- G6PC3 | c.880C>A p.L294M | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99291311; called by muse, mutect2, varscan2
- GCG | c.110A>C p.Q37P | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.418); catalogued as COSV64962207; called by muse, mutect2
- GDF2 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs782569430; called by muse, mutect2, varscan2
- GEMIN4 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | catalogued as COSV56747495; called by muse, mutect2
- GLB1L | c.260A>T p.H87L | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55478796; called by muse, mutect2
- GRIN2B | c.2491C>A p.L831I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV74207316, COSV74207686; called by muse, mutect2, varscan2
- GUCY2F | c.3029C>A p.A1010D | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54301210, COSV54308265; called by muse, mutect2, varscan2
- H2AC20 | c.315G>C p.Q105H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100479709, COSV58613151; called by muse, mutect2
- H2AP | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.246); catalogued as COSV99049491; called by muse, mutect2, varscan2
- HAP1 | c.1975C>G p.P659A (on ENST00000310778 / NM_001367460.1; = p.P607A on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.563); catalogued as COSV100169856; called by muse, mutect2
- HECW1 | c.2990T>A p.F997Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV67839507; called by muse, mutect2, varscan2
- HEG1 | c.1001T>A p.V334E | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV60765408; called by muse, mutect2, varscan2
- HERC2 | c.3470C>G p.A1157G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.098); catalogued as COSV55349193; called by muse, mutect2, varscan2
- HOXD10 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as COSV50899722, COSV99982884; called by muse, mutect2
- HPX | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56420560; called by muse, mutect2, varscan2
- HRNR | c.798G>C p.Q266H | Missense Mutation (SNP) | VAF 25/806 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV64262496; called by muse, mutect2
- HS3ST5 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV57151601; called by muse, mutect2
- HSD3B7 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV52682058; called by muse, mutect2, varscan2
- IARS2 | c.1635C>G p.I545M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV56963815; called by muse, mutect2, varscan2
- IGFBP1 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV51875455; called by muse, mutect2, varscan2
- IGSF11 | c.1234G>T p.E412* (on ENST00000393775 / NM_001015887.3; = p.E411* on NM_152538.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/158 reads (11%) | catalogued as rs1345830252, COSV61178178; called by muse, mutect2, varscan2
- ITGB3 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71385212; called by muse, mutect2, varscan2
- ITIH3 | c.1386C>T p.G462= | Splice Region (SNP) | VAF 3/40 reads (8%) | catalogued as COSV69650141; called by muse, mutect2
- ITSN1 | c.2360G>C p.G787A | Missense Mutation (SNP) | VAF 50/195 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66085912; called by muse, mutect2, varscan2
- JAKMIP3 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs750472478, COSV53829007; called by mutect2, varscan2
- JAM2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369585750; called by muse, mutect2, varscan2
- KCNA5 | c.600A>G p.I200M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV52908552; called by muse, mutect2
- KCNC2 | c.1563G>C p.Q521H | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54379146; called by muse, mutect2
- KCNK2 | c.528C>G p.I176M (on ENST00000444842 / NM_001017425.3; = p.I161M on NM_014217.4) | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as COSV67210095; called by muse, mutect2
- KIDINS220 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV56751851; called by muse, mutect2, varscan2
- KIF1B | c.4261C>G p.L1421V (on ENST00000377086 / NM_001365952.1; = p.L1375V on NM_015074.3) | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV55815750; called by muse, mutect2
- KIF5A | c.2597G>T p.R866M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54058910; called by muse, mutect2, varscan2
- KRT37 | c.145G>C p.V49L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56657563, COSV56659961; called by muse, mutect2, varscan2
- KRTAP8-1 | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.01); catalogued as COSV61598354; called by muse, mutect2, varscan2
- KSR1 | c.1468G>A p.A490T (on ENST00000644974 / NM_001367810.1; = p.A353T on NM_014238.2) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV52038967; called by muse, mutect2
- LAMB1 | c.4201C>A p.P1401T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as COSV55969962, COSV55970901; called by muse, mutect2
- LILRB1 | c.788C>A p.S263* (on ENST00000427581; = p.S227* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV61121484; called by muse, mutect2, varscan2
- LILRB4 | c.914C>A p.A305D | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99553772, COSV99553999; called by muse, mutect2, varscan2
- LRFN2 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV57834326; called by muse, mutect2, varscan2
- LRP1B | c.7342C>G p.H2448D | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV67272329; called by muse, mutect2
- LRRK2 | c.4645G>A p.D1549N | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54169701; called by muse, mutect2
- LUC7L | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV53460613; called by muse, mutect2
- MBD3 | c.751G>T p.V251L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as COSV50085594; called by muse, mutect2, varscan2
- MCF2 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58494641; called by muse, mutect2, varscan2
- MKI67 | c.5093G>C p.R1698T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV64076783; called by muse, mutect2, varscan2
- MKI67 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV64076786; called by muse, mutect2
- MRPL55 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV99686955; called by muse, mutect2
- MTTP | c.1978C>T p.H660Y | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV55509659; called by muse, mutect2
- MUC16 | c.7092del p.S2365Qfs*9 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | catalogued as COSV101198023; called by mutect2, pindel, varscan2
- MX2 | c.577+1del | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs1460138511; called by mutect2, pindel, varscan2
- MXRA5 | c.3174G>T p.K1058N | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.19); catalogued as COSV54249574; called by muse, mutect2
- MYCBP2 | c.3556A>C p.K1186Q (on ENST00000357337; = p.K1224Q on NM_015057.5) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV62038249; called by muse, mutect2, varscan2
- MYH11 | c.4460C>G p.S1487C | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55568144, COSV55568931; called by muse, mutect2
- MYH3 | c.1817T>A p.V606E | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56869780; called by muse, mutect2
- MYLIP | c.1061C>G p.S354* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as COSV62767627; called by muse, mutect2, varscan2
- MYO3A | c.4203G>T p.E1401D | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV56321998, COSV56348301; called by muse, mutect2, varscan2
- MYOM2 | c.3808A>T p.K1270* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV50768837; called by muse, mutect2, varscan2
- NAV1 | c.2998A>C p.S1000R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55225949; called by muse, mutect2
- NCAPD3 | c.1795G>C p.A599P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101599379, COSV73258482; called by muse, mutect2, varscan2
- NCAPD3 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101599380; called by muse, mutect2, varscan2
- NEK10 | c.2960G>T p.W987L | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV55365105; called by muse, mutect2
- NLRP2 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54760078; called by muse, mutect2, varscan2
- NOS2 | c.3071T>G p.I1024S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV58227232; called by muse, mutect2
- NUP214 | c.4145A>T p.K1382M | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV63913041; called by muse, mutect2, varscan2
- NUP42 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs765112038, COSV99331108; called by muse, mutect2, varscan2
- NXF3 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV67705096; called by muse, mutect2, varscan2
- NXF5 | n.600+1G>T | Splice Site (SNP) | VAF 25/147 reads (17%) | catalogued as COSV53793299; called by muse, mutect2, varscan2
- OBSCN | c.10540G>T p.D3514Y | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52825848; called by muse, mutect2, varscan2
- ODF2 | c.1050G>T p.Q350H (on ENST00000434106 / NM_153433.2; = p.Q326H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.664); catalogued as COSV63548857; called by muse, mutect2
- OGA | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.554); catalogued as COSV63383297; called by muse, mutect2
- OR10K2 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV59222658; called by muse, mutect2, varscan2
- OR10S1 | c.895C>G p.P299A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73343033; called by muse, mutect2, varscan2
- OR2A2 | c.788C>G p.S263C | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68872521; called by muse, mutect2, varscan2
- OR2T33 | c.454G>C p.A152P | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58817790; called by muse, mutect2, varscan2
- OR4C13 | c.392C>A p.T131N | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as rs1555015773, COSV73648919; called by muse, mutect2, varscan2
- OR4C16 | c.440G>T p.W147L | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58944230; called by muse, mutect2, varscan2
- OR51G1 | c.660C>A p.Y220* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV58968475, COSV58969599; called by muse, mutect2, varscan2
- OR52E2 | c.710A>T p.K237M | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100384861; called by muse, mutect2, varscan2
- OR5AN1 | c.251C>A p.S84Y | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100004405; called by muse, mutect2, varscan2
- OR5J2 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV104394843, COSV56620700; called by muse, mutect2, varscan2
- OR8U1 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100164031; called by muse, varscan2
- OR9K2 | c.299C>G p.S100C (on ENST00000305377; = p.S78C on NM_001005243.1) | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100543852, COSV59532370, COSV59533391; called by muse, mutect2
- PALM2AKAP2 | c.1492G>A p.D498N (on ENST00000259318 / NM_001136562.3; = p.D729N on NM_007203.5) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52179512; called by muse, mutect2, varscan2
- PAQR8 | c.463C>G p.Q155E | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62443640; called by muse, mutect2
- PCDH11X | c.3707C>A p.P1236Q | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.282); catalogued as COSV53502097; called by muse, mutect2, varscan2
- PCDHA7 | c.1093C>G p.P365A | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.248); catalogued as COSV65347353; called by muse, mutect2
- PCLO | c.13359G>T p.L4453F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.935); catalogued as COSV61633988, COSV61664110; called by muse, mutect2, varscan2
- PCLO | c.6136G>A p.G2046S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.306); catalogued as COSV61664123; called by muse, mutect2
- PCLO | c.2468G>T p.R823L | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); catalogued as rs201550435, COSV61622003, COSV61645934; called by muse, mutect2, varscan2
- PCNX2 | c.4051G>T p.V1351L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.285); catalogued as COSV50882918; called by muse, mutect2, varscan2
- PDE6B | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV55330699; called by muse, mutect2, varscan2
- PGLYRP3 | c.963C>A p.N321K | Missense Mutation (SNP) | VAF 61/315 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV51952697; called by muse, mutect2, varscan2
- PHC1 | c.2417A>T p.Y806F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as COSV99134261; called by muse, mutect2, varscan2
- PKD1 | c.10218G>C p.K3406N (on ENST00000262304 / NM_001009944.3; = p.K3405N on NM_000296.4) | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV51925208; called by muse, mutect2
- PLEKHA7 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs752097358, COSV63050791; called by muse, mutect2, varscan2
- PLXNA4 | c.909T>A p.S303R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV58158803; called by muse, mutect2, varscan2
- PNLIP | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 7/84 reads (8%) | catalogued as COSV65041953; called by muse, mutect2
- PRF1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM040245, COSV64615820; called by muse, mutect2, varscan2
- PRSS1 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61194928; called by muse, varscan2
- PSG4 | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 170/638 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54940702; called by muse, mutect2, varscan2
- PSG5 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 45/428 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV61655288; called by muse, mutect2, varscan2
- PTCHD4 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59783889; called by muse, mutect2, varscan2
- PTPN3 | c.1931G>T p.G644V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52710810; called by muse, mutect2, varscan2
- PTPRZ1 | c.2776C>G p.P926A | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV66445191; called by muse, mutect2, varscan2
- RANBP2 | c.4210G>T p.V1404F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51708381; called by muse, mutect2, varscan2
- RASGRP3 | c.1823C>A p.A608D (on ENST00000402538 / NM_001349975.2; = p.A607D on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV67825031; called by muse, mutect2
- RELN | c.1004T>A p.V335E | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV59032622; called by muse, mutect2
- RGL3 | c.394G>T p.V132L | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV100710504, COSV62699161; called by muse, mutect2, varscan2
- RGN | c.456T>G p.I152M | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100282465; called by muse, mutect2, varscan2
- RNF183 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99938117; called by muse, mutect2, varscan2
- RNF213 | c.2337G>T p.E779D | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.068); catalogued as COSV60630099; called by muse, mutect2, varscan2
- RNF31 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53761230; called by muse, mutect2, varscan2
- RP1L1 | c.3872A>T p.Q1291L | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV66759975; called by muse, mutect2, varscan2
- RPGRIP1 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99251415; called by muse, mutect2
- RYR1 | c.8654C>G p.T2885R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV62110130; called by muse, mutect2, varscan2
- RYR1 | c.9058A>G p.T3020A | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.294); catalogued as COSV62110137; called by muse, mutect2, varscan2
- SAA2 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.858); catalogued as COSV56778039; called by muse, mutect2, varscan2
- SAFB2 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV53045006, COSV53045037; called by muse, mutect2, varscan2
- SEC16A | c.4159G>T p.A1387S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as COSV51540231; called by muse, mutect2, varscan2
- SERINC3 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as COSV99667894; called by muse, mutect2
- SETD2 | c.3187A>T p.R1063* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV57451203; called by muse, mutect2, varscan2
- SEZ6L2 | c.1018G>T p.G340C (on ENST00000308713 / NM_001114099.3; = p.G270C on NM_012410.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143818590, COSV58103696; called by muse, mutect2, varscan2
- SF3B1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 37/519 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV59226806; called by muse, mutect2
- SLAMF1 | c.671C>A p.P224Q | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV52501994; called by muse, mutect2, varscan2
- SLC14A2 | c.2135C>G p.A712G | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV54914306; called by muse, mutect2, varscan2
- SLC29A4 | c.1240G>A p.G414S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV51876739; called by muse, mutect2, varscan2
- SLC5A10 | c.1242G>T p.R414= (on ENST00000395645 / NM_001042450.4; = p.R430= on NM_152351.5) | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV52414503; called by muse, mutect2, varscan2
- SLC6A15 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as COSV57029383; called by muse, mutect2
- SLITRK5 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | catalogued as COSV61524170, COSV61526090; called by muse, mutect2, varscan2
- SPNS3 | c.996G>T p.R332S | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV61072188; called by muse, mutect2, varscan2
- SRCAP | c.9439G>T p.G3147W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV52680462; called by muse, mutect2, varscan2
- STK11 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as CM981865, COSV58820140; called by muse, mutect2, varscan2
- STK3 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as COSV101372401; called by muse, mutect2
- STK32B | c.347T>A p.V116E | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51512043; called by muse, mutect2
- SUGCT | c.1196G>T p.R399M (on ENST00000335693 / NM_001193313.2; = p.R425M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100000648; called by muse, mutect2
- SVEP1 | c.5297G>T p.G1766V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52843843, COSV99928719; called by muse, mutect2, varscan2
- SWI5 | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1271849228, COSV60793069; called by muse, mutect2
- TACR1 | c.324C>G p.H108Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0.043); catalogued as COSV100538034; called by muse, mutect2, varscan2
- TACR3 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150288991, CM119300; called by muse, mutect2, varscan2
- TENM4 | c.5842G>A p.D1948N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs754933715, COSV53615521; called by muse, mutect2, varscan2
- TEX15 | c.1342G>A p.E448K (on ENST00000256246; = p.E831K on NM_001350162.2) | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV56353324; called by muse, mutect2, varscan2
- TGFB2 | c.1135T>A p.C379S | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65111021; called by muse, mutect2
- THADA | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1287909838, COSV67092737; called by muse, mutect2
- THAP12 | c.1645C>G p.Q549E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52613027; called by muse, mutect2
- THOC6 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs770236483, COSV50188214; called by muse, varscan2
- TMEM132D | c.2673G>T p.Q891H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV67158974, COSV67160671; called by muse, mutect2, varscan2
- TNFAIP2 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.251); catalogued as COSV60696085; called by muse, mutect2
- TOP1 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV63694483; called by muse, mutect2, varscan2
- TP53 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53581107; called by muse, mutect2, varscan2
- TRAIP | c.1237-1G>T p.X413_splice | Splice Site (SNP) | VAF 5/61 reads (8%) | catalogued as COSV58916636; called by muse, mutect2
- TRAK2 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV60274915; called by muse, mutect2, varscan2
- TRIM10 | c.881T>C p.M294T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs558693422, COSV64999988; called by muse, mutect2, varscan2
- TRIM43 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV55527814; called by muse, mutect2, varscan2
- TRIM49 | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.04); catalogued as COSV100316162; called by muse, mutect2, varscan2
- TTLL9 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.375); catalogued as COSV100207041; called by muse, mutect2
- TUBA3C | c.1225G>T p.V409L | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV68029580; called by muse, mutect2, varscan2
- TUBB8 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.206); catalogued as COSV100226114; called by muse, mutect2, varscan2
- UBOX5 | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53909470; called by muse, mutect2, varscan2
- URGCP | c.64G>T p.A22S (on ENST00000453200 / NM_001077663.3; = p.A13S on NM_017920.4) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.075); catalogued as COSV56252486; called by muse, mutect2, varscan2
- UTP14A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 21/166 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV64102604; called by muse, mutect2, varscan2
- VPS13B | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV62156196; called by muse, varscan2
- WDFY3 | c.1967C>G p.S656C | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55713292; called by muse, mutect2
- WNK4 | c.1721C>G p.A574G | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV55910195; called by muse, mutect2, varscan2
- ZEB2 | c.1353del p.T452Pfs*2 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as CD072524; called by mutect2, pindel, varscan2
- ZFP14 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99525219; called by muse, mutect2, varscan2
- ZFPM2 | c.888C>A p.S296R | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV65874793, COSV65875756; called by muse, mutect2
- ZNF214 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV53483582; called by muse, mutect2
- ZNF260 | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 28/251 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV101591066; called by muse, mutect2, varscan2
- ZNF335 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59820098, COSV59820884; called by muse, mutect2, varscan2
- ZNF415 | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV54704912, COSV99701481; called by muse, mutect2
- ZNF436 | c.594G>C p.E198D | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.241); catalogued as COSV58359440; called by muse, mutect2
- ZNF439 | c.443G>T p.C148F | Missense Mutation (SNP) | VAF 48/201 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV58311039; called by muse, mutect2, varscan2
- ZNF479 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58639178; called by muse, mutect2
- ZNF516 | c.450A>C p.R150S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV71587625; called by muse, mutect2
- ZNF639 | c.998A>C p.H333P | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100418458; called by muse, mutect2, varscan2
- ZNF649 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV56817771, COSV56818462; called by muse, mutect2, varscan2
- ZNF649 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100725473; called by muse, mutect2, varscan2
- ZNF804B | c.131C>G p.T44R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV60853630; called by muse, mutect2, varscan2
- ADGRB2 | c.2750del p.L917Qfs*8 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel*, varscan2
- CAPRIN2 | c.1710G>T p.W570C | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DST | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GMPPA | c.410del p.F137Sfs*55 | Frame Shift Del (DEL) | VAF 15/163 reads (9%) | called by mutect2, pindel, varscan2
- KIF26A | c.1912dup p.C638Lfs*2 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- MRC1 | c.3179C>A p.S1060* | Nonsense Mutation (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- MRC1 | c.3799G>C p.G1267R | Missense Mutation (SNP) | VAF 99/528 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- MYH8 | c.397dup p.W133Lfs*30 | Frame Shift Ins (INS) | VAF 18/153 reads (12%) | called by mutect2, varscan2
- OR1C1 | c.940del p.Q314Nfs*7 | Frame Shift Del (DEL) | VAF 45/181 reads (25%) | called by mutect2, pindel, varscan2
- PLCL1 | c.1980del p.W660* | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- SERPING1 | c.333_341del p.D112_P114del | In Frame Del (DEL) | VAF 12/117 reads (10%) | called by mutect2, pindel
- TAS2R20 | c.801del p.F267Lfs*13 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- TRIM11 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- USP7 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCC11 | c.2580C>A p.S860= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV62325755; called by muse, mutect2, varscan2
- ABCG5 | c.159C>A p.P53= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV53213391; called by muse, mutect2
- ABL2 | c.615G>T p.G205= (on ENST00000502732 / NM_007314.4; = p.G190= on NM_005158.5) | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV61020417; called by muse, mutect2, varscan2
- ADH6 | c.324T>C p.S108= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV52957797; called by muse, mutect2
- APBB1 | c.1242G>T p.G414= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as COSV54980312; called by muse, mutect2, varscan2
- BTBD11 | c.1479C>A p.L493= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV55036846; called by muse, mutect2, varscan2
- CAMSAP2 | c.3246A>G p.E1082= (on ENST00000236925 / NM_001297707.2; = p.E1071= on NM_203459.3) | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs1056585417, COSV52677067; called by muse, mutect2, varscan2
- CDH23 | c.5904G>A p.V1968= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1425427267, COSV56488383; called by muse, varscan2
- CLEC4E | c.459G>A p.V153= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV55227264; called by muse, mutect2, varscan2
- COL16A1 | c.3084G>A p.L1028= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV54713484; called by muse, mutect2, varscan2
- COL5A1 | c.4806G>T p.V1602= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100880209; called by muse, mutect2, varscan2
- CORO2A | c.831C>T p.F277= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV59664834; called by muse, mutect2
- CPT1C | c.393C>G p.S131= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV54922045; called by muse, mutect2, varscan2
- CTNND1 | c.921G>T p.R307= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV62386095; called by muse, mutect2, varscan2
- CYP7A1 | c.879G>T p.A293= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV56963055, COSV56965703; called by muse, mutect2
- DDI1 | c.732C>G p.L244= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as COSV56389527, COSV56393400; called by muse, mutect2, varscan2
- DGLUCY | c.21G>T p.L7= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV54088864; called by muse, mutect2, varscan2
- DISP1 | c.3936G>T p.V1312= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99451598; called by muse, mutect2, varscan2
- DRC1 | c.984A>G p.E328= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV56535295; called by muse, mutect2
- EPHB1 | c.2253G>T p.L751= | Silent (SNP) | VAF 31/173 reads (18%) | catalogued as rs765122124, COSV67670816; called by muse, mutect2, varscan2
- ERICH3 | c.855T>C p.S285= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV58617740; called by muse, mutect2
- EXO1 | c.1899C>T p.F633= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV62219837; called by muse, mutect2
- EXOC3 | c.2157A>T p.P719= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV59268645; called by muse, mutect2, varscan2
- GCG | c.108C>G p.S36= | Silent (SNP) | VAF 21/298 reads (7%) | catalogued as COSV64962218; called by muse, mutect2
- GOLGA2 | c.2778C>T p.L926= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs762337817, COSV57848921; called by mutect2, varscan2
- GPNMB | c.669C>T p.I223= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as rs763628675, COSV51700907; called by muse, mutect2, varscan2
- HCAR2 | c.900C>A p.S300= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV61025777; called by muse, mutect2, varscan2
- HCCS | c.510C>T p.A170= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100335785; called by muse, mutect2, varscan2
- KCNC2 | c.897C>T p.V299= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1404068585, COSV54379166; called by muse, mutect2, varscan2
- KLHL3 | c.1374C>T p.S458= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV59057488; called by muse, mutect2, varscan2
- KRT36 | c.463C>T p.L155= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV60204691; called by muse, mutect2
- KRTAP19-7 | c.189T>C p.Y63= | Silent (SNP) | VAF 11/204 reads (5%) | catalogued as rs1333612259, COSV58366590; called by muse, mutect2
- LCK | c.996A>C p.S332= | Silent (SNP) | VAF 24/278 reads (9%) | catalogued as COSV60742596; called by muse, mutect2
- LILRB4 | c.1245G>A p.R415= (on ENST00000391733 / NM_001278428.3; = p.R414= on NM_001278426.3) | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV54408485; called by muse, mutect2, varscan2
- MACF1 | c.13392C>A p.L4464= (on ENST00000372915; = p.L2397= on NM_012090.5) | Silent (SNP) | VAF 20/259 reads (8%) | catalogued as COSV57142928; called by muse, mutect2
- MAK | c.1744C>A p.R582= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as COSV57565193, COSV57567648; called by muse, mutect2, varscan2
- MUC16 | c.38535C>A p.P12845= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs759265589, COSV67491790; called by muse, mutect2, varscan2
- MYD88 | c.792C>T p.F264= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV57180062; called by muse, mutect2, varscan2
- MYO18B | c.7317G>T p.V2439= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV59147860; called by muse, mutect2, varscan2
- NCSTN | c.61C>T p.L21= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs199694056, COSV54109186; called by muse, mutect2, varscan2
- NDUFS1 | c.1642C>T p.L548= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV51913660, COSV99261279; called by muse, mutect2
- NGRN | c.21C>T p.L7= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs750810675, COSV58961746; called by muse, mutect2, varscan2
- NRK | c.3258A>C p.T1086= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV54606188; called by muse, mutect2, varscan2
- OR10H5 | c.388C>T p.L130= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs909285954, COSV100454768, COSV58277505, COSV58278562; called by muse, mutect2
- OR10R2 | c.411G>A p.V137= | Silent (SNP) | VAF 21/551 reads (4%) | catalogued as COSV63769487; called by muse, mutect2
- OR6Y1 | c.93C>A p.L31= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV56929175, COSV56931286; called by muse, mutect2, varscan2
- OR8S1 | c.111G>T p.L37= | Silent (SNP) | VAF 23/242 reads (10%) | catalogued as COSV59600839; called by muse, mutect2
- PALD1 | c.747G>C p.V249= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as COSV54978662; called by muse, mutect2, varscan2
- PARP16 | c.792A>T p.R264= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as COSV56036582; called by muse, mutect2, varscan2
- PCDH19 | c.276G>C p.L92= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV55263599, COSV55271052; called by muse, mutect2, varscan2
- PCDHB11 | c.1644C>A p.R548= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs781884111, COSV100697089; called by muse, mutect2, varscan2
- PDE9A | c.318G>A p.L106= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV52331273; called by muse, mutect2, varscan2
- PEG3 | c.1995C>A p.T665= | Silent (SNP) | VAF 31/234 reads (13%) | catalogued as rs772262119, COSV55646689, COSV99686882; called by muse, mutect2, varscan2
- PNLDC1 | c.1359C>A p.L453= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV51707969; called by muse, varscan2
- PREX2 | c.1782A>G p.L594= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV55797685; called by muse, mutect2
- PSMG1 | c.546C>T p.G182= | Silent (SNP) | VAF 15/142 reads (11%) | catalogued as COSV100521917; called by muse, mutect2, varscan2
- RAPH1 | c.2718C>T p.P906= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as rs1321013808, COSV55589274, COSV55590014; called by muse, mutect2, varscan2
- RELN | c.5178G>A p.K1726= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV59032615; called by muse, mutect2
- RFX6 | c.2406T>C p.Y802= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as rs766725782, COSV60588614; called by muse, mutect2, varscan2
- RGS12 | c.3360A>T p.P1120= | Silent (SNP) | VAF 12/206 reads (6%) | catalogued as COSV58752301; called by muse, mutect2
- RNF157 | c.1770T>C p.N590= | Silent (SNP) | VAF 30/199 reads (15%) | catalogued as COSV53948126; called by muse, mutect2, varscan2
- RSBN1 | c.150T>G p.A50= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV54735116, COSV99792940; called by muse, mutect2
- SERINC3 | c.108G>T p.T36= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs201041892; called by muse, mutect2
- SF3B3 | c.3132G>T p.V1044= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV56790951; called by muse, mutect2, varscan2
- SI | c.3741G>T p.V1247= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV52299973; called by muse, mutect2, varscan2
- SLC25A2 | c.87C>T p.P29= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs782713558, COSV53404978, COSV99508356; called by muse, mutect2, varscan2
- SNX29 | c.522G>T p.A174= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as COSV60070117; called by muse, mutect2, varscan2
- TGFB1 | c.456G>A p.R152= | Silent (SNP) | VAF 16/199 reads (8%) | catalogued as rs757266734, COSV55726495; called by muse, mutect2
- TMED9 | c.294G>A p.L98= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs1024705727, COSV60264079; called by muse, mutect2
- TMEM200A | c.597C>T p.S199= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV51659244; called by muse, mutect2, varscan2
- TNFAIP2 | c.1041G>T p.V347= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV60696095; called by muse, mutect2
- TUBB8 | c.759G>C p.L253= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100226116; called by muse, mutect2, varscan2
- URB2 | c.1476G>T p.S492= | Silent (SNP) | VAF 16/213 reads (8%) | catalogued as COSV51040506; called by muse, mutect2
- VEGFC | c.441G>A p.A147= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs560722685, COSV54594504; called by muse, mutect2, varscan2
- WEE2 | c.318C>A p.P106= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as COSV66880044; called by muse, mutect2, varscan2
- ZIC1 | c.1317T>A p.S439= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV51557752; called by muse, mutect2, varscan2
- ZSCAN1 | c.393C>T p.V131= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as rs751937817, COSV56608300; called by muse, mutect2, varscan2
- DPP6 | c.*376C>T | 3'UTR (SNP) | VAF 8/114 reads (7%) | catalogued as rs1287289097, COSV100126867; called by muse, mutect2
- FAM153CP | n.420C>T | RNA (SNP) | VAF 28/365 reads (8%) | catalogued as COSV101228667; called by muse, mutect2
- IGFN1 | c.1242-62G>T | Intron (SNP) | VAF 5/54 reads (9%) | catalogued as COSV55184028, COSV99811598; called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.11C>G | RNA (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2, varscan2
- KRT18P55 | n.664C>A | RNA (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- MICAL3 | c.2605+129C>G | Intron (SNP) | VAF 3/49 reads (6%) | catalogued as COSV99262378; called by muse, mutect2
- RNF217-AS1 | n.1309C>G | RNA (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570543 C>A | 5'Flank (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23890C>A | Intron (SNP) | VAF 8/124 reads (6%) | catalogued as COSV67449327; called by muse, mutect2
